Somatic mutation profile of tumor specimen ALCH-B273-TTP1-A (aliquot ALCH-B273-TTP1-A-1-0-D-A76N-36) from ALCHEMIST case ALCH-B273, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 65.4 years (23,897 days).
Specimen ALCH-B273-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ff8eb02d-268b-4d2c-8b18-b2472d51262f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B273-NB1-A (Blood Derived Normal), aliquot ALCH-B273-NB1-A-1-0-D-A76N-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9286c8d7-18d8-4ed5-a5ef-ab722ec18c5a

The open-access MAF lists 475 somatic variants for this specimen: 334 protein-altering or splice-affecting, 87 silent, 54 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 273, Silent 87, Nonsense Mutation 31, Frame Shift Del 15, Intron 15, Splice Site 12, RNA 10, 3'UTR 9, 5'Flank 8, 5'UTR 8, 3'Flank 4, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1862A>G p.N621S (on ENST00000288602 / NM_001374244.1; = p.N581S on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 134/402 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as rs121913370, COSV56058108, COSV56106422, COSV56110832; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- STK11 | c.291-1G>T p.X97_splice | Splice Site (SNP) | VAF 35/121 reads (29%) | hotspot (GDC flag); catalogued as rs112675807, CS004815, CS147061, CS982372, COSV58820323; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCC8 | c.1218C>A p.N406K | Missense Mutation (SNP) | VAF 131/579 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.214); catalogued as rs1487039219; called by muse, mutect2, varscan2
- ACAP3 | c.1766C>T p.S589L | Missense Mutation (SNP) | VAF 49/334 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.091); catalogued as rs778945613; called by muse, mutect2, varscan2
- ACTRT1 | c.310C>A p.Q104K | Missense Mutation (SNP) | VAF 68/360 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.117); catalogued as COSV64419070; called by muse, mutect2, varscan2
- ADGRG4 | c.4937T>A p.L1646H | Missense Mutation (SNP) | VAF 60/355 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.005); catalogued as COSV54960729; called by muse, mutect2, varscan2
- AP2A1 | c.1647C>G p.I549M | Missense Mutation (SNP) | VAF 108/659 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.173); catalogued as rs1328496268; called by muse, mutect2, varscan2
- APLP1 | c.1138G>A p.V380I | Missense Mutation (SNP) | VAF 100/458 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.57); catalogued as rs751820034, COSV55701988; called by muse, mutect2, varscan2
- APOB | c.10049T>A p.L3350Q | Missense Mutation (SNP) | VAF 26/156 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs756338430; called by muse, mutect2, varscan2
- ARFIP2 | c.775G>C p.E259Q | Missense Mutation (SNP) | VAF 56/372 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.417); catalogued as COSV54446903; called by muse, mutect2, varscan2
- ARHGAP33 | c.335G>T p.R112L | Missense Mutation (SNP) | VAF 60/257 reads (23%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.155); catalogued as COSV50119830; called by muse, mutect2, varscan2
- ARID2 | c.3814C>T p.R1272* | Nonsense Mutation (SNP) | VAF 44/192 reads (23%) | catalogued as COSV57596882; called by muse, mutect2, varscan2
- ATP7B | c.2356-2A>T p.X786_splice | Splice Site (SNP) | VAF 129/603 reads (21%) | catalogued as HS050008; called by muse, mutect2, varscan2
- BCORL1 | c.3388C>A p.Q1130K | Missense Mutation (SNP) | VAF 28/194 reads (14%) | SIFT tolerated (0.15); PolyPhen benign (0.039); catalogued as COSV54411557; called by muse, varscan2
- C11orf49 | c.553C>T p.R185* | Nonsense Mutation (SNP) | VAF 46/222 reads (21%) | catalogued as rs759118065, COSV99562539; called by muse, mutect2, varscan2
- C1orf94 | c.314A>C p.Q105P | Missense Mutation (SNP) | VAF 21/84 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.015); catalogued as COSV64915766; called by mutect2, varscan2
- CACNA1E | c.851G>T p.G284V | Missense Mutation (SNP) | VAF 238/972 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62392498, COSV62416591; called by muse, mutect2, varscan2
- CADM3 | c.94C>A p.Q32K (on ENST00000368125 / NM_001127173.3; = p.Q66K on NM_021189.5) | Missense Mutation (SNP) | VAF 160/457 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); catalogued as rs1010695144; called by muse, mutect2, varscan2
- CCDC168 | c.11747del p.P3916Rfs*21 | Frame Shift Del (DEL) | VAF 92/259 reads (36%) | catalogued as COSV100488001, COSV59424116; called by mutect2, pindel, varscan2
- CDH12 | c.163G>T p.G55C | Missense Mutation (SNP) | VAF 74/445 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66453491; called by muse, mutect2, varscan2
- CDH5 | c.1868G>T p.R623L | Missense Mutation (SNP) | VAF 22/99 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV58519976; called by muse, mutect2
- CNBD1 | c.282-1G>A p.X94_splice | Splice Site (SNP) | VAF 4/35 reads (11%) | catalogued as rs1199266903; called by muse, mutect2
- CTSH | c.493-8T>C | Splice Region (SNP) | VAF 107/486 reads (22%) | catalogued as rs1301847530; called by muse, mutect2, varscan2
- DFFB | c.602A>G p.Q201R | Missense Mutation (SNP) | VAF 40/245 reads (16%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as rs753253553; called by muse, mutect2
- DNM3 | c.687G>T p.R229S | Missense Mutation (SNP) | VAF 85/528 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV100798322; called by muse, mutect2, varscan2
- DOCK9 | c.347A>G p.Y116C (on ENST00000376460 / NM_001366676.2; = p.Y117C on NM_015296.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 34/232 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs891190858; called by muse, varscan2
- EFHC1 | c.145G>A p.G49R | Missense Mutation (SNP) | VAF 268/761 reads (35%) | SIFT tolerated (0.14); PolyPhen benign (0.01); catalogued as rs760025678; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- EFHC1 | c.1100T>A p.I367N | Missense Mutation (SNP) | VAF 142/453 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.602); catalogued as COSV100932098; called by muse, mutect2, varscan2
- EIF4G1 | c.694C>T p.P232S (on ENST00000346169 / NM_198241.3; = p.P36S on NM_004953.5) | Missense Mutation (SNP) | VAF 50/231 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.683); catalogued as rs1230725389; called by muse, mutect2, varscan2
- EPHA3 | c.1061G>C p.R354P | Missense Mutation (SNP) | VAF 47/285 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60696940; called by muse, mutect2, varscan2
- EYA2 | c.722C>T p.P241L | Missense Mutation (SNP) | VAF 43/252 reads (17%) | SIFT tolerated (0.42); PolyPhen benign (0.245); catalogued as rs761803191, COSV57942134, COSV57950428; called by muse, mutect2, varscan2
- F5 | c.907G>A p.E303K | Missense Mutation (SNP) | VAF 113/862 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0.024); catalogued as COSV63123853; called by muse, mutect2, varscan2
- F7 | c.752C>G p.A251G | Missense Mutation (SNP) | VAF 54/430 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as CM051920, CM073037, COSV60646194, COSV60647098; called by muse, varscan2
- FAM200B | c.1669G>A p.E557K | Missense Mutation (SNP) | VAF 29/203 reads (14%) | SIFT tolerated (0.68); PolyPhen benign (0.054); catalogued as rs1364600080; called by muse, mutect2, varscan2
- FERMT1 | c.1348G>A p.E450K | Missense Mutation (SNP) | VAF 119/460 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs1478026917; called by muse, mutect2, varscan2
- FLG | c.8713G>C p.E2905Q | Missense Mutation (SNP) | VAF 134/1282 reads (10%) | SIFT tolerated (0.31); PolyPhen benign (0.007); catalogued as COSV64243100, COSV64244907; called by muse, mutect2, varscan2
- GATA3 | c.227C>T p.P76L | Missense Mutation (SNP) | VAF 220/765 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.502); catalogued as rs1315804209; called by muse, mutect2, varscan2
- GOLGA6L10 | c.1172G>A p.R391Q | Missense Mutation (SNP) | VAF 340/2508 reads (14%) | SIFT tolerated (0.14); PolyPhen benign (0.017); catalogued as rs760863645; called by muse, varscan2
- GPHN | c.10G>T p.E4* | Nonsense Mutation (SNP) | VAF 120/621 reads (19%) | catalogued as COSV59473595; called by muse, mutect2, varscan2
- GRIA4 | c.1740C>A p.D580E | Missense Mutation (SNP) | VAF 38/209 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV56922996; called by muse, varscan2
- HELZ2 | c.2326C>T p.R776W (on ENST00000467148 / NM_001037335.2; = p.R207W on NM_033405.3) | Missense Mutation (SNP) | VAF 31/178 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.744); catalogued as rs143150352; called by muse, mutect2, varscan2
- HOXA1 | c.180G>C p.Q60H | Missense Mutation (SNP) | VAF 21/134 reads (16%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.627); catalogued as COSV56067596; called by muse, mutect2, varscan2
- HR | c.2433G>T p.E811D | Missense Mutation (SNP) | VAF 96/326 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); catalogued as COSV99060565; called by muse, mutect2, varscan2
- HSP90AB1 | c.52C>G p.Q18E | Missense Mutation (SNP) | VAF 64/445 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.48); catalogued as COSV62334504, COSV62336891; called by muse, mutect2, varscan2
- IGLV11-55 | c.238G>A p.G80R | Missense Mutation (SNP) | VAF 71/329 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66504486; called by muse, mutect2, varscan2
- IL1RAPL1 | c.1708G>T p.E570* | Nonsense Mutation (SNP) | VAF 45/372 reads (12%) | catalogued as COSV56266184; called by muse, mutect2, varscan2
- JAKMIP1 | c.299C>A p.A100E | Missense Mutation (SNP) | VAF 54/265 reads (20%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.999); catalogued as COSV51528035; called by muse, mutect2, varscan2
- KEAP1 | c.704A>G p.D235G | Missense Mutation (SNP) | VAF 44/164 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as COSV50660006; called by muse, mutect2, varscan2
- KIAA0825 | c.156A>G p.I52M | Missense Mutation (SNP) | VAF 44/153 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.778); catalogued as rs1562592440, COSV56948454; called by muse, varscan2
- KMT5B | c.1277C>T p.S426L | Missense Mutation (SNP) | VAF 40/235 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs199872518, COSV58566383; called by muse, mutect2, varscan2
- LCN1 | c.354C>A p.Y118* | Nonsense Mutation (SNP) | VAF 70/487 reads (14%) | catalogued as COSV55017892; called by muse, mutect2, varscan2
- LGR4 | c.1652T>C p.V551A | Missense Mutation (SNP) | VAF 25/113 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.251); catalogued as rs780736159; called by muse, mutect2, varscan2
- LMAN1 | c.937G>T p.D313Y | Missense Mutation (SNP) | VAF 138/666 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99195328; called by muse, mutect2, varscan2
- LRP1B | c.7436G>T p.C2479F | Missense Mutation (SNP) | VAF 28/269 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV67188032; called by muse, mutect2, varscan2
- LRP1B | c.5611C>T p.R1871C | Missense Mutation (SNP) | VAF 26/98 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.791); catalogued as rs779772138; called by muse, mutect2
- MAN2B2 | c.271C>T p.Q91* | Nonsense Mutation (SNP) | VAF 51/211 reads (24%) | catalogued as rs781557986; called by muse, mutect2, varscan2
- MLLT6 | c.1614G>T p.L538F | Missense Mutation (SNP) | VAF 146/670 reads (22%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as rs930684700; called by muse, mutect2, varscan2
- MORF4L1 | c.276G>T p.W92C (on ENST00000331268 / NM_206839.2; = p.W53C on NM_006791.4) | Missense Mutation (SNP) | VAF 93/400 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV100489203; called by muse, mutect2, varscan2
- MYCBPAP | c.32G>A p.R11K | Missense Mutation (SNP) | VAF 75/392 reads (19%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as rs777292355, COSV60406395; called by muse, mutect2, varscan2
- NAT1 | c.379C>T p.R127C | Missense Mutation (SNP) | VAF 71/213 reads (33%) | SIFT tolerated (0.22); PolyPhen benign (0.073); catalogued as rs759800046, COSV56986301; called by muse, mutect2, varscan2
- NDC80 | c.232G>C p.E78Q | Missense Mutation (SNP) | VAF 26/286 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as COSV55246813; called by muse, mutect2
- NF1 | c.6922-1G>T p.X2308_splice (on ENST00000358273 / NM_001042492.3; = p.X2287_splice on NM_000267.3) | Splice Site (SNP) | VAF 97/496 reads (20%) | catalogued as CS1311546, COSV62201682; called by muse, mutect2, varscan2
- NOS2 | c.2383C>A p.P795T | Missense Mutation (SNP) | VAF 29/159 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0.33); catalogued as COSV58221784; called by muse, mutect2, varscan2
- NXPE4 | c.1447G>A p.D483N (on ENST00000375478 / NM_001077639.2; = p.D199N on NM_017678.3) | Missense Mutation (SNP) | VAF 76/389 reads (20%) | SIFT tolerated (0.47); PolyPhen benign (0.03); catalogued as rs1295199044; called by muse, mutect2, varscan2
- OR2T3 | c.719G>C p.R240T | Missense Mutation (SNP) | VAF 91/293 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.506); catalogued as COSV62082246; called by muse, mutect2, varscan2
- OR4X2 | c.133A>G p.R45G | Missense Mutation (SNP) | VAF 108/583 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as rs1565358494; called by muse, mutect2, varscan2
- OR51I2 | c.226G>C p.A76P | Missense Mutation (SNP) | VAF 23/126 reads (18%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.671); catalogued as COSV58298386; called by muse, mutect2, varscan2
- OR6C1 | c.148G>A p.D50N | Missense Mutation (SNP) | VAF 87/436 reads (20%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.048); catalogued as rs1450409682; called by muse, mutect2, varscan2
- OR6K2 | c.553C>A p.R185S | Missense Mutation (SNP) | VAF 106/381 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.051); catalogued as rs752799224, COSV100656655, COSV62744312; called by muse, mutect2, varscan2
- OR8H1 | c.424G>T p.A142S | Missense Mutation (SNP) | VAF 35/188 reads (19%) | SIFT tolerated (0.8); PolyPhen benign (0.007); catalogued as rs142532321, CM125354, COSV57292940, COSV57293327; called by muse, mutect2, varscan2
- OR8I2 | c.346G>T p.G116* | Nonsense Mutation (SNP) | VAF 67/300 reads (22%) | catalogued as COSV56170774; called by muse, mutect2, varscan2
- PCDHGB3 | c.1510T>A p.Y504N | Missense Mutation (SNP) | VAF 102/509 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs1375493299; called by muse, mutect2, varscan2
- PCED1B | c.1013del p.P338Qfs*99 | Frame Shift Del (DEL) | VAF 71/284 reads (25%) | catalogued as COSV101423681; called by mutect2, pindel, varscan2
- PFKFB1 | c.549C>A p.D183E | Missense Mutation (SNP) | VAF 85/534 reads (16%) | PolyPhen benign (0.001); catalogued as COSV100895549, COSV66629137; called by muse, mutect2, varscan2
- PKP1 | c.442C>G p.Q148E | Missense Mutation (SNP) | VAF 258/845 reads (31%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.621); catalogued as rs1322541781; called by muse, mutect2, varscan2
- PLCB1 | c.1940G>T p.G647V | Missense Mutation (SNP) | VAF 88/419 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1555786704; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PLEKHO2 | c.911G>T p.R304M | Missense Mutation (SNP) | VAF 17/87 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.34); catalogued as COSV60263311; called by muse, mutect2, varscan2
- PRKG1 | c.525G>T p.M175I | Missense Mutation (SNP) | VAF 158/705 reads (22%) | SIFT tolerated (0.42); PolyPhen benign (0.025); catalogued as COSV64784997; called by muse, mutect2, varscan2
- PTPN14 | c.1154A>G p.N385S | Missense Mutation (SNP) | VAF 86/646 reads (13%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.97); catalogued as rs774224839; called by muse, mutect2, varscan2
- QSER1 | c.3094A>C p.S1032R (on ENST00000399302; = p.S1161R on NM_001076786.3) | Missense Mutation (SNP) | VAF 37/179 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.03); catalogued as COSV67901790; called by muse, mutect2, varscan2
- RANBP2 | c.2336C>T p.T779I | Missense Mutation (SNP) | VAF 131/708 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.031); catalogued as rs780643942; called by muse, mutect2, varscan2
- RIN2 | c.528G>T p.M176I (on ENST00000255006 / NM_001242581.1; = p.M127I on NM_018993.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 54/315 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.015); catalogued as COSV54795688; called by muse, mutect2, varscan2
- RP1 | c.634G>T p.V212L | Missense Mutation (SNP) | VAF 112/723 reads (15%) | SIFT tolerated (0.67); PolyPhen benign (0.306); catalogued as COSV99606238; called by muse, mutect2, varscan2
- RTP1 | c.502G>T p.E168* | Nonsense Mutation (SNP) | VAF 39/138 reads (28%) | catalogued as COSV56618008; called by muse, mutect2, varscan2
- SCN11A | c.4033C>T p.Q1345* | Nonsense Mutation (SNP) | VAF 72/451 reads (16%) | catalogued as rs751009800; called by muse, mutect2, varscan2
- SETD1A | c.931C>T p.R311C | Missense Mutation (SNP) | VAF 70/381 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as rs760563687, COSV52686790; called by muse, mutect2, varscan2
- SLC4A11 | c.905G>A p.R302K | Missense Mutation (SNP) | VAF 26/770 reads (3%) | SIFT tolerated (0.26); PolyPhen benign (0.006); catalogued as COSV101195929; called by muse, mutect2
- SLC9A2 | c.1253G>T p.R418M | Missense Mutation (SNP) | VAF 100/526 reads (19%) | SIFT tolerated (0.17); PolyPhen benign (0.343); catalogued as rs773952288; called by muse, mutect2, varscan2
- SMYD1 | c.38C>A p.T13N | Missense Mutation (SNP) | VAF 71/336 reads (21%) | SIFT tolerated (0.54); PolyPhen benign (0.003); catalogued as COSV70225310; called by mutect2, varscan2
- SPATA31E1 | c.728del p.P243Lfs*50 | Frame Shift Del (DEL) | VAF 59/380 reads (16%) | catalogued as COSV57795557; called by mutect2, pindel, varscan2
- SPG7 | c.2250G>A p.M750I (on ENST00000268704; = p.M757I on NM_003119.4) | Missense Mutation (SNP) | VAF 36/596 reads (6%) | SIFT tolerated (0.17); PolyPhen benign (0.06); catalogued as COSV51951506; called by muse, mutect2
- STK10 | c.937G>T p.E313* | Nonsense Mutation (SNP) | VAF 102/522 reads (20%) | catalogued as rs889609207; called by muse, mutect2, varscan2
- SUMF1 | c.968C>T p.S323F | Missense Mutation (SNP) | VAF 111/517 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.379); catalogued as rs1218513120; called by muse, mutect2, varscan2
- SWT1 | c.374A>G p.H125R | Missense Mutation (SNP) | VAF 18/113 reads (16%) | SIFT tolerated (0.77); PolyPhen benign (0); catalogued as COSV62256715; called by muse, mutect2, varscan2
- SYT10 | c.611C>A p.T204N | Missense Mutation (SNP) | VAF 111/590 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.771); catalogued as rs368570091, COSV57344200; called by muse, mutect2, varscan2
- TENT5D | c.1111C>A p.P371T | Missense Mutation (SNP) | VAF 24/103 reads (23%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.003); catalogued as COSV57635074, COSV57639213; called by muse, mutect2, varscan2
- TNRC18 | c.1026del p.K343Rfs*247 | Frame Shift Del (DEL) | VAF 17/63 reads (27%) | catalogued as rs1172601563; called by mutect2, pindel, varscan2
- TPRX1 | c.395C>A p.P132Q | Missense Mutation (SNP) | VAF 105/476 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.031); catalogued as COSV100445864; called by muse, mutect2, varscan2
- TRPC4AP | c.547C>T p.R183C | Missense Mutation (SNP) | VAF 27/147 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.642); catalogued as rs201809090; called by muse, mutect2, varscan2
- VEGFA | c.323G>C p.R108P (on ENST00000523873 / NM_001171623.1; = p.R288P on NM_003376.6) | Missense Mutation (SNP) | VAF 164/1016 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100035629; called by muse, mutect2, varscan2
- VGLL2 | c.676G>A p.A226T | Missense Mutation (SNP) | VAF 17/258 reads (7%) | SIFT tolerated (0.88); PolyPhen benign (0.003); catalogued as rs1374764275; called by muse, mutect2
- WNK2 | c.735G>T p.M245I | Missense Mutation (SNP) | VAF 59/288 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV99941841; called by muse, mutect2, varscan2
- XIRP2 | c.8867G>A p.R2956Q (on ENST00000628543; = p.R3131Q on NM_152381.6) | Missense Mutation (SNP) | VAF 67/342 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs757745970, COSV54685802, COSV54722839; called by muse, mutect2, varscan2
- XYLT1 | c.2707G>C p.E903Q | Missense Mutation (SNP) | VAF 40/201 reads (20%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.584); catalogued as COSV54475980, COSV54477959; called by muse, varscan2
- ZNF236 | c.2626G>T p.E876* | Nonsense Mutation (SNP) | VAF 53/263 reads (20%) | catalogued as COSV53482793; called by muse, mutect2, varscan2
- ZSCAN22 | c.1379G>A p.G460E | Missense Mutation (SNP) | VAF 65/286 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61639193; called by muse, mutect2, varscan2
- ABI3BP | c.1949C>T p.P650L | Missense Mutation (SNP) | VAF 79/447 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.94); called by muse, mutect2, varscan2
- ACVR2B | c.815C>T p.S272F | Missense Mutation (SNP) | VAF 127/659 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ADGRE2 | c.866del p.G289Afs*49 | Frame Shift Del (DEL) | VAF 56/281 reads (20%) | called by mutect2, pindel, varscan2
- ADGRG4 | c.3806C>A p.P1269H | Missense Mutation (SNP) | VAF 35/125 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.615); called by muse, mutect2, varscan2
- AHNAK | c.6186A>T p.K2062N | Missense Mutation (SNP) | VAF 180/1037 reads (17%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- AKAP4 | c.1366C>T p.H456Y | Missense Mutation (SNP) | VAF 50/301 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ANK2 | c.3842C>T p.P1281L | Missense Mutation (SNP) | VAF 125/655 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ANKRD34C | c.479G>A p.G160D | Missense Mutation (SNP) | VAF 44/308 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ANP32A | c.201G>C p.K67N | Missense Mutation (SNP) | VAF 54/224 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.515); called by muse, varscan2
- AP2A2 | c.963-8_969del p.X321_splice | Splice Site (DEL) | VAF 36/191 reads (19%) | called by mutect2, pindel, varscan2
- AQP6 | c.473G>T p.C158F | Missense Mutation (SNP) | VAF 74/367 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ARFIP2 | c.112G>T p.V38L | Missense Mutation (SNP) | VAF 38/201 reads (19%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.97); called by muse, varscan2
- ARFIP2 | c.111G>T p.Q37H | Missense Mutation (SNP) | VAF 39/201 reads (19%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.986); called by muse, varscan2
- ARHGAP30 | c.1344G>T p.E448D | Missense Mutation (SNP) | VAF 33/212 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.918); called by muse, mutect2, varscan2
- ARHGAP33 | c.664G>T p.E222* | Nonsense Mutation (SNP) | VAF 12/49 reads (24%) | called by muse, mutect2, varscan2
- ARHGEF2 | c.1331A>T p.E444V (on ENST00000361247 / NM_001162383.2; = p.E416V on NM_004723.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 163/969 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- ARMCX4 | c.172C>T p.P58S | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT tolerated, low confidence (0.3); PolyPhen possibly damaging (0.81); called by muse, mutect2, varscan2
- AURKAIP1 | c.339G>T p.E113D | Missense Mutation (SNP) | VAF 40/275 reads (15%) | SIFT tolerated (0.24); PolyPhen benign (0.115); called by muse, mutect2, varscan2
- BCAN | c.277G>T p.A93S | Missense Mutation (SNP) | VAF 79/297 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- BMP10 | c.1008del p.W337Gfs*58 | Frame Shift Del (DEL) | VAF 45/286 reads (16%) | called by mutect2, pindel, varscan2
- BNC2 | c.1465C>A p.H489N | Missense Mutation (SNP) | VAF 145/749 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- BRINP1 | c.130G>T p.D44Y | Missense Mutation (SNP) | VAF 124/774 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, varscan2
- C1orf112 | c.1420G>C p.A474P | Missense Mutation (SNP) | VAF 43/493 reads (9%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.902); called by muse, mutect2
- C4orf54 | c.262G>T p.E88* | Nonsense Mutation (SNP) | VAF 72/264 reads (27%) | called by muse, mutect2, varscan2
- CACNA1B | c.2196G>T p.K732N | Missense Mutation (SNP) | VAF 52/239 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- CACNA1C | c.5018T>A p.L1673H | Missense Mutation (SNP) | VAF 72/439 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- CASK | c.264C>A p.Y88* | Nonsense Mutation (SNP) | VAF 30/271 reads (11%) | called by muse, mutect2, varscan2
- CCDC120 | c.742C>A p.Q248K | Missense Mutation (SNP) | VAF 20/198 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.413); called by muse, mutect2
- CCDC166 | c.77C>A p.P26Q | Missense Mutation (SNP) | VAF 45/111 reads (41%) | SIFT tolerated (0.5); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- CCNE1 | c.1078A>T p.I360L | Missense Mutation (SNP) | VAF 28/128 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CDH11 | c.1084G>T p.G362C | Missense Mutation (SNP) | VAF 78/473 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CDH6 | c.272T>C p.I91T | Missense Mutation (SNP) | VAF 29/190 reads (15%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.895); called by muse, mutect2
- CDH8 | c.2294C>A p.T765N | Missense Mutation (SNP) | VAF 100/459 reads (22%) | SIFT tolerated (0.45); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- CELSR1 | c.6025G>T p.G2009C | Missense Mutation (SNP) | VAF 115/543 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CFAP74 | c.3731A>T p.H1244L | Missense Mutation (SNP) | VAF 51/316 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.244); called by muse, mutect2, varscan2
- CFAP74 | c.1073G>A p.R358K | Missense Mutation (SNP) | VAF 59/319 reads (18%) | SIFT tolerated (0.19); PolyPhen benign (0.401); called by muse, mutect2, varscan2
- CHD5 | c.754G>T p.V252L | Missense Mutation (SNP) | VAF 59/303 reads (19%) | SIFT tolerated (0.59); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- CHD7 | c.2191C>G p.P731A | Missense Mutation (SNP) | VAF 65/345 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- CKAP4 | c.1382C>G p.S461* | Nonsense Mutation (SNP) | VAF 46/278 reads (17%) | called by muse, mutect2, varscan2
- CLCA2 | c.2276C>A p.P759H | Missense Mutation (SNP) | VAF 176/859 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.65); called by muse, mutect2, varscan2
- CLCN1 | c.1651G>T p.G551C | Missense Mutation (SNP) | VAF 386/1174 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CLIP1 | c.3735G>T p.K1245N (on ENST00000620786 / NM_001247997.1; = p.K1234N on NM_002956.2) | Missense Mutation (SNP) | VAF 55/144 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CNGA2 | c.1755T>A p.D585E | Missense Mutation (SNP) | VAF 17/96 reads (18%) | SIFT tolerated (0.14); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- CNGA3 | c.104C>A p.A35D | Missense Mutation (SNP) | VAF 51/320 reads (16%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0); called by muse, mutect2, varscan2
- CNGB3 | c.586C>A p.P196T | Missense Mutation (SNP) | VAF 216/589 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.41); called by muse, mutect2, varscan2
- CNTNAP4 | c.2811G>C p.L937F | Missense Mutation (SNP) | VAF 68/348 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.851); called by muse, varscan2
- COL11A1 | c.2557-2A>G p.X853_splice | Splice Site (SNP) | VAF 75/415 reads (18%) | called by muse, mutect2, varscan2
- COL13A1 | c.1001C>A p.A334E (on ENST00000398978 / NM_001130103.2; = p.A277E on NM_080798.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 89/404 reads (22%) | SIFT tolerated (0.75); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- COL17A1 | c.-11-1G>A | Splice Site (SNP) | VAF 77/587 reads (13%) | called by muse, mutect2, varscan2
- COLQ | c.366+1G>T p.X122_splice | Splice Site (SNP) | VAF 107/613 reads (17%) | called by muse, mutect2, varscan2
- CRACD | c.1127A>C p.E376A | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.356); called by muse, mutect2, varscan2
- CREBL2 | c.91G>C p.E31Q | Missense Mutation (SNP) | VAF 149/737 reads (20%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- CRYBB2 | c.114C>A p.C38* | Nonsense Mutation (SNP) | VAF 150/693 reads (22%) | called by muse, mutect2, varscan2
- CSTF2T | c.1708A>C p.T570P | Missense Mutation (SNP) | VAF 273/1053 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.069); called by muse, mutect2, varscan2
- CTNND2 | c.2503C>G p.P835A | Missense Mutation (SNP) | VAF 44/361 reads (12%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CUL7 | c.3793G>C p.E1265Q | Missense Mutation (SNP) | VAF 150/875 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CXorf66 | c.18T>G p.C6W | Missense Mutation (SNP) | VAF 39/167 reads (23%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.485); called by muse, mutect2, varscan2
- CYP2B6 | c.901G>T p.E301* | Nonsense Mutation (SNP) | VAF 140/699 reads (20%) | called by muse, mutect2, varscan2
- DCAF4L2 | c.652C>T p.Q218* | Nonsense Mutation (SNP) | VAF 33/574 reads (6%) | called by muse, mutect2
- DCSTAMP | c.191C>A p.S64Y | Missense Mutation (SNP) | VAF 330/849 reads (39%) | SIFT tolerated (1); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- DENND3 | c.2731G>A p.E911K | Missense Mutation (SNP) | VAF 32/162 reads (20%) | SIFT tolerated (0.53); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- DNAH3 | c.7411G>A p.E2471K | Missense Mutation (SNP) | VAF 36/208 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.805); called by muse, mutect2, varscan2
- DOCK11 | c.1516G>T p.A506S | Missense Mutation (SNP) | VAF 35/240 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.41); called by muse, mutect2, varscan2
- DOK7 | c.1252C>A p.H418N | Missense Mutation (SNP) | VAF 50/197 reads (25%) | SIFT tolerated (0.24); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- DPEP2 | c.166G>C p.G56R | Missense Mutation (SNP) | VAF 30/180 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.029); called by muse, varscan2
- DST | c.19453C>G p.L6485V (on ENST00000361203 / NM_001374722.1; = p.L4182V on NM_015548.5) | Missense Mutation (SNP) | VAF 102/294 reads (35%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.747); called by muse, varscan2
- DST | c.13373-1G>A p.X4458_splice (on ENST00000361203 / NM_001374722.1; = p.X2046_splice on NM_015548.5) | Splice Site (SNP) | VAF 69/266 reads (26%) | called by muse, mutect2, varscan2
- DYNC2H1 | c.8018G>T p.G2673V | Missense Mutation (SNP) | VAF 41/187 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.555); called by muse, mutect2, varscan2
- EDEM2 | c.738G>T p.W246C | Missense Mutation (SNP) | VAF 64/334 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- EFHC1 | c.1099A>T p.I367F | Missense Mutation (SNP) | VAF 142/455 reads (31%) | SIFT tolerated (0.05); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- EGFL6 | c.901C>A p.P301T | Missense Mutation (SNP) | VAF 82/602 reads (14%) | SIFT tolerated (0.22); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- FAM163A | c.380C>A p.T127K | Missense Mutation (SNP) | VAF 121/351 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.221); called by muse, mutect2, varscan2
- FAM189A1 | c.1399G>T p.E467* | Nonsense Mutation (SNP) | VAF 89/310 reads (29%) | called by muse, mutect2, varscan2
- FAM90A8P | c.52C>A p.Q18K | Missense Mutation (SNP) | VAF 55/530 reads (10%) | SIFT tolerated (0.17); PolyPhen benign (0.092); called by muse, mutect2, varscan2
- FAT3 | c.5805C>G p.N1935K | Missense Mutation (SNP) | VAF 34/185 reads (18%) | SIFT tolerated (0.43); PolyPhen benign (0.076); called by muse, mutect2, varscan2
- FCRL6 | c.850A>T p.R284* | Nonsense Mutation (SNP) | VAF 111/335 reads (33%) | called by muse, mutect2, varscan2
- FLNC | c.7908C>G p.S2636R | Missense Mutation (SNP) | VAF 25/874 reads (3%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.974); called by muse, mutect2
- FOS | c.320C>A p.S107Y | Missense Mutation (SNP) | VAF 52/232 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.141); called by muse, mutect2, varscan2
- FOXA2 | c.886G>T p.E296* (on ENST00000377115 / NM_153675.3; = p.E302* on NM_021784.5) | Nonsense Mutation (SNP) | VAF 6/45 reads (13%) | called by muse, mutect2, varscan2
- FSIP2 | c.17146A>T p.N5716Y | Missense Mutation (SNP) | VAF 45/233 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- FUT6 | c.863C>A p.A288D | Missense Mutation (SNP) | VAF 69/413 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- GABRR3 | c.269A>T p.H90L | Missense Mutation (SNP) | VAF 45/297 reads (15%) | SIFT deleterious (0); PolyPhen benign (0); called by muse, mutect2, varscan2
- GABRR3 | c.268C>A p.H90N | Missense Mutation (SNP) | VAF 44/294 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0); called by muse, mutect2, varscan2
- GALNT1 | c.949G>T p.G317* | Nonsense Mutation (SNP) | VAF 38/197 reads (19%) | called by muse, mutect2, varscan2
- GLCE | c.437_438del p.Y146* | Frame Shift Del (DEL) | VAF 72/474 reads (15%) | called by mutect2, pindel, varscan2
- GLRA3 | c.392T>C p.L131S | Missense Mutation (SNP) | VAF 84/377 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); called by muse, mutect2, varscan2
- GPAT4 | c.412G>C p.E138Q | Missense Mutation (SNP) | VAF 76/509 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- GPATCH1 | c.956G>T p.G319V | Missense Mutation (SNP) | VAF 91/490 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.94); called by muse, mutect2, varscan2
- GPATCH2 | c.46G>T p.G16W | Missense Mutation (SNP) | VAF 49/382 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.818); called by muse, mutect2, varscan2
- GRIN2B | c.4334A>T p.D1445V | Missense Mutation (SNP) | VAF 33/178 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.843); called by muse, mutect2, varscan2
- GRXCR2 | c.638G>T p.G213V | Missense Mutation (SNP) | VAF 32/174 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HCN1 | c.1616G>A p.G539E | Missense Mutation (SNP) | VAF 66/427 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HDGFL1 | c.233G>T p.G78V | Missense Mutation (SNP) | VAF 247/688 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HECTD2 | c.803T>A p.L268Q | Missense Mutation (SNP) | VAF 53/247 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- HEPH | c.2992G>C p.D998H (on ENST00000343002; = p.D731H on NM_014799.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 39/329 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HHLA1 | c.1528G>C p.V510L | Missense Mutation (SNP) | VAF 122/503 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.243); called by muse, mutect2, varscan2
- HIVEP2 | c.2833G>T p.A945S | Missense Mutation (SNP) | VAF 49/171 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.723); called by muse, mutect2, varscan2
- IGFN1 | c.2467C>A p.P823T (on ENST00000295591 / NM_001367841.1; = p.P3280T on NM_001164586.2) | Missense Mutation (SNP) | VAF 55/483 reads (11%) | SIFT tolerated (0.63); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- IGSF3 | c.3178C>T p.P1060S (on ENST00000369486 / NM_001007237.3; = p.P1080S on NM_001542.4) | Missense Mutation (SNP) | VAF 71/322 reads (22%) | SIFT tolerated (0.39); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- IL20RA | c.974A>T p.Q325L | Missense Mutation (SNP) | VAF 41/189 reads (22%) | SIFT tolerated (0.05); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- IL3RA | c.569C>A p.A190D | Missense Mutation (SNP) | VAF 81/312 reads (26%) | SIFT tolerated (0.73); PolyPhen possibly damaging (0.749); called by muse, mutect2, varscan2
- ISLR2 | c.478C>G p.R160G | Missense Mutation (SNP) | VAF 73/430 reads (17%) | SIFT tolerated (0.28); PolyPhen benign (0.295); called by muse, mutect2, varscan2
- ITGA2B | c.1873G>A p.E625K | Missense Mutation (SNP) | VAF 126/745 reads (17%) | SIFT tolerated (0.24); PolyPhen benign (0.134); called by muse, mutect2, varscan2
- JAKMIP3 | c.1099C>A p.Q367K | Missense Mutation (SNP) | VAF 50/322 reads (16%) | SIFT tolerated (0.38); PolyPhen benign (0.075); called by muse, mutect2, varscan2
- JAKMIP3 | c.1238A>G p.E413G | Missense Mutation (SNP) | VAF 74/196 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.6); called by muse, mutect2, varscan2
- KCNQ2 | c.1370C>A p.S457Y (on ENST00000359125 / NM_172107.4; = p.S429Y on NM_004518.6) | Missense Mutation (SNP) | VAF 87/366 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.713); called by muse, mutect2, varscan2
- KIF21B | c.2899G>C p.E967Q | Missense Mutation (SNP) | VAF 54/396 reads (14%) | SIFT tolerated (0.12); PolyPhen benign (0.305); called by muse, mutect2, varscan2
- KMT5C | c.1088_1089insA p.H365Pfs*96 | Frame Shift Ins (INS) | VAF 30/211 reads (14%) | called by mutect2, pindel, varscan2
- LAMB4 | c.3565C>A p.L1189I | Missense Mutation (SNP) | VAF 203/512 reads (40%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.564); called by muse, mutect2, varscan2
- LAS1L | c.907C>A p.R303S | Missense Mutation (SNP) | VAF 72/510 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.097); called by muse, varscan2
- LASP1 | c.158G>T p.C53F | Missense Mutation (SNP) | VAF 54/221 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); called by muse, mutect2, varscan2
- LINGO1 | c.1612G>A p.E538K | Missense Mutation (SNP) | VAF 121/598 reads (20%) | SIFT tolerated (0.33); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- LONP2 | c.1435G>T p.A479S | Missense Mutation (SNP) | VAF 110/545 reads (20%) | SIFT tolerated (0.17); PolyPhen benign (0.24); called by muse, mutect2, varscan2
- LOXHD1 | c.4925C>A p.A1642D | Missense Mutation (SNP) | VAF 58/218 reads (27%) | SIFT tolerated (0.11); PolyPhen benign (0.155); called by muse, mutect2, varscan2
- LRRC7 | c.2743C>T p.H915Y (on ENST00000651989 / NM_001370785.2; = p.H882Y on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 56/420 reads (13%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- LY6K | c.322A>T p.M108L | Missense Mutation (SNP) | VAF 176/652 reads (27%) | SIFT tolerated (1); PolyPhen benign (0); called by mutect2, varscan2
- MAGEE2 | c.794A>T p.E265V | Missense Mutation (SNP) | VAF 86/586 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.587); called by muse, mutect2, varscan2
- MBTPS2 | c.1402G>T p.G468* | Nonsense Mutation (SNP) | VAF 51/494 reads (10%) | called by muse, mutect2, varscan2
- MBTPS2 | c.1403G>T p.G468V | Missense Mutation (SNP) | VAF 50/505 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MICAL3 | c.4498G>A p.E1500K | Missense Mutation (SNP) | VAF 56/224 reads (25%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.257); called by mutect2, varscan2
- MICAL3 | c.4016G>T p.G1339V | Missense Mutation (SNP) | VAF 112/544 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MKI67 | c.574G>T p.G192C | Missense Mutation (SNP) | VAF 52/291 reads (18%) | SIFT tolerated (0.28); PolyPhen benign (0); called by muse, mutect2, varscan2
- MROH9 | c.2308T>A p.L770I | Missense Mutation (SNP) | VAF 43/401 reads (11%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.889); called by muse, mutect2, varscan2
- MS4A18 | c.858_859del p.A287Sfs*? (on ENST00000398983; = p.A289Sfs*70 on NM_001354471.1) | Frame Shift Del (DEL) | VAF 17/102 reads (17%) | called by mutect2, pindel*
- MXRA5 | c.1480G>A p.G494R | Missense Mutation (SNP) | VAF 24/198 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MXRA5 | c.1165G>T p.V389L | Missense Mutation (SNP) | VAF 46/458 reads (10%) | SIFT tolerated (0.18); PolyPhen benign (0.022); called by muse, mutect2
- NBEAL2 | c.495G>C p.E165D | Missense Mutation (SNP) | VAF 54/266 reads (20%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- NBEAL2 | c.2070del p.F691Sfs*128 | Frame Shift Del (DEL) | VAF 35/242 reads (14%) | called by mutect2, pindel, varscan2
- NCKAP1 | c.1209G>T p.K403N | Missense Mutation (SNP) | VAF 52/238 reads (22%) | SIFT tolerated (0.3); PolyPhen benign (0.003); called by muse, varscan2
- NF1 | c.8254G>T p.E2752* (on ENST00000358273 / NM_001042492.3; = p.E2731* on NM_000267.3) | Nonsense Mutation (SNP) | VAF 152/741 reads (21%) | called by muse, mutect2, varscan2
- NGEF | c.676G>T p.E226* | Nonsense Mutation (SNP) | VAF 40/218 reads (18%) | called by mutect2, varscan2
- NKAP | c.208C>T p.Q70* | Nonsense Mutation (SNP) | VAF 32/192 reads (17%) | called by muse, mutect2, varscan2
- NLGN3 | c.55G>A p.G19S | Missense Mutation (SNP) | VAF 29/180 reads (16%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- NOXO1 | c.592C>A p.H198N (on ENST00000397280 / NM_172168.3; = p.H192N on NM_144603.4) | Missense Mutation (SNP) | VAF 35/120 reads (29%) | SIFT tolerated (0.21); PolyPhen benign (0.316); called by muse, mutect2, varscan2
- NRG3 | c.1157+1del p.X386_splice | Splice Site (DEL) | VAF 46/294 reads (16%) | called by mutect2, pindel, varscan2
- NRXN1 | c.342G>C p.W114C | Missense Mutation (SNP) | VAF 38/191 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.123); called by muse, mutect2, varscan2
- NUF2 | c.23G>C p.R8T | Missense Mutation (SNP) | VAF 33/171 reads (19%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- NUP133 | c.3280G>A p.E1094K | Missense Mutation (SNP) | VAF 18/234 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.828); called by muse, mutect2
- NUP210 | c.3781G>T p.D1261Y | Missense Mutation (SNP) | VAF 76/396 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); called by muse, mutect2, varscan2
- NWD2 | c.3842T>C p.V1281A | Missense Mutation (SNP) | VAF 44/206 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.079); called by muse, varscan2
- NXNL1 | c.241G>T p.D81Y | Missense Mutation (SNP) | VAF 40/204 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OBSCN | c.7883G>C p.R2628P | Missense Mutation (SNP) | VAF 59/373 reads (16%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.711); called by muse, mutect2, varscan2
- OBSCN | c.15491A>T p.K5164M | Missense Mutation (SNP) | VAF 169/559 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- OR4Q2 | c.350C>A p.T117K | Missense Mutation (SNP) | VAF 67/154 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.744); called by muse, mutect2, varscan2
- OR51F2 | c.463G>T p.V155F | Missense Mutation (SNP) | VAF 35/175 reads (20%) | SIFT tolerated (0.27); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- OR56A1 | c.518G>T p.G173V | Missense Mutation (SNP) | VAF 46/231 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.099); called by muse, varscan2
- OR6Y1 | c.926C>A p.T309N | Missense Mutation (SNP) | VAF 78/268 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.443); called by muse, mutect2, varscan2
- OSBP | c.2158G>T p.D720Y | Missense Mutation (SNP) | VAF 114/610 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PA2G4 | c.1084G>A p.A362T | Missense Mutation (SNP) | VAF 92/581 reads (16%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.869); called by muse, mutect2, varscan2
- PARP4 | c.1807G>A p.A603T | Missense Mutation (SNP) | VAF 78/373 reads (21%) | SIFT tolerated (0.89); PolyPhen benign (0); called by muse, mutect2, varscan2
- PCDH8 | c.2451C>A p.N817K | Missense Mutation (SNP) | VAF 24/122 reads (20%) | SIFT tolerated (0.13); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PCDHB6 | c.721T>A p.F241I | Missense Mutation (SNP) | VAF 78/384 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- PCDHGB2 | c.2322G>T p.L774F | Missense Mutation (SNP) | VAF 105/577 reads (18%) | SIFT tolerated (0.71); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- PCDHGB5 | c.1729_1730del p.A577Cfs*31 | Frame Shift Del (DEL) | VAF 59/428 reads (14%) | called by pindel, varscan2
- PCDHGC5 | c.806C>A p.P269Q | Missense Mutation (SNP) | VAF 54/288 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.053); called by muse, mutect2, varscan2
- PCSK4 | c.1211G>T p.R404L | Missense Mutation (SNP) | VAF 68/262 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.111); called by muse, mutect2, varscan2
- PDE10A | c.2171A>T p.Q724L | Missense Mutation (SNP) | VAF 71/495 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.228); called by muse, mutect2, varscan2
- PDK1 | c.148G>T p.A50S | Missense Mutation (SNP) | VAF 22/94 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PGR | c.1865G>T p.C622F | Missense Mutation (SNP) | VAF 103/508 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PHKA2 | c.1482G>T p.L494F | Missense Mutation (SNP) | VAF 36/378 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- PI4KA | c.4021_4031del p.R1341Gfs*40 | Frame Shift Del (DEL) | VAF 42/367 reads (11%) | called by mutect2, pindel, varscan2
- PIK3C2G | c.1626C>A p.S542R | Missense Mutation (SNP) | VAF 36/138 reads (26%) | SIFT tolerated (0.25); PolyPhen benign (0); called by muse, mutect2, varscan2
- PIWIL3 | c.730A>T p.N244Y | Missense Mutation (SNP) | VAF 65/305 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- PLS3 | c.878G>C p.S293T | Missense Mutation (SNP) | VAF 34/199 reads (17%) | SIFT tolerated (0.33); PolyPhen benign (0.127); called by muse, mutect2, varscan2
- PLXNA4 | c.3639+1G>T p.X1213_splice | Splice Site (SNP) | VAF 39/244 reads (16%) | called by muse, mutect2, varscan2
- POGZ | c.482G>T p.R161L | Missense Mutation (SNP) | VAF 55/483 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.688); called by muse, mutect2, varscan2
- PPFIA2 | c.1763A>G p.D588G | Missense Mutation (SNP) | VAF 28/162 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.043); called by muse, mutect2
- PRSS38 | c.52C>A p.L18I | Missense Mutation (SNP) | VAF 37/157 reads (24%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.906); called by muse, mutect2, varscan2
- PSMA8 | c.161A>T p.K54M | Missense Mutation (SNP) | VAF 67/365 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.419); called by muse, mutect2, varscan2
- PTPRF | c.5071G>T p.G1691C | Missense Mutation (SNP) | VAF 60/259 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RORC | c.415G>C p.A139P | Missense Mutation (SNP) | VAF 12/128 reads (9%) | SIFT tolerated (0.19); PolyPhen benign (0.001); called by muse, mutect2
- RRAS2 | c.451G>T p.V151L | Missense Mutation (SNP) | VAF 42/164 reads (26%) | SIFT tolerated (0.05); PolyPhen benign (0.063); called by muse, mutect2, varscan2
- RTL4 | c.880C>A p.L294I | Missense Mutation (SNP) | VAF 23/163 reads (14%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.633); called by muse, mutect2, varscan2
- RUNX1T1 | c.1577G>T p.C526F (on ENST00000265814 / NM_001198628.1; = p.C499F on NM_004349.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 107/341 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RYR2 | c.11458G>T p.V3820L | Missense Mutation (SNP) | VAF 34/343 reads (10%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.907); called by muse, mutect2
- SAG | c.1120G>C p.D374H | Missense Mutation (SNP) | VAF 73/410 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.656); called by muse, varscan2
- SATL1 | c.533G>C p.S178T (on ENST00000395409; = p.S365T on NM_001012980.2) | Missense Mutation (SNP) | VAF 49/226 reads (22%) | SIFT tolerated (0.46); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- SCARA3 | c.1243G>T p.E415* | Nonsense Mutation (SNP) | VAF 200/633 reads (32%) | called by muse, mutect2, varscan2
- SCML4 | c.1072G>C p.A358P | Missense Mutation (SNP) | VAF 113/483 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- SCN7A | c.3000G>A p.W1000* | Nonsense Mutation (SNP) | VAF 56/335 reads (17%) | called by muse, mutect2, varscan2
- SEC23A | c.2020_2035del p.D674Kfs*78 | Frame Shift Del (DEL) | VAF 118/341 reads (35%) | called by mutect2, pindel, varscan2
- SENP7 | c.35C>T p.S12L | Missense Mutation (SNP) | VAF 122/663 reads (18%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- SERPINB8 | c.224G>T p.S75I | Missense Mutation (SNP) | VAF 72/489 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.079); called by muse, mutect2, varscan2
- SH3TC2 | c.1719C>G p.I573M | Missense Mutation (SNP) | VAF 23/524 reads (4%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.472); called by muse, mutect2
- SHISA6 | c.1084C>A p.P362T (on ENST00000409168 / NM_001173461.1; = p.P413T on NM_207386.4) | Missense Mutation (SNP) | VAF 47/244 reads (19%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.452); called by muse, mutect2, varscan2
- SIAE | c.229+1G>T p.X77_splice | Splice Site (SNP) | VAF 105/659 reads (16%) | called by muse, mutect2, varscan2
- SLC15A5 | c.213G>T p.K71N | Missense Mutation (SNP) | VAF 56/303 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.067); called by muse, varscan2
- SLC22A16 | c.103G>T p.G35C | Missense Mutation (SNP) | VAF 14/27 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLC25A13 | c.1714G>T p.E572* | Nonsense Mutation (SNP) | VAF 159/1073 reads (15%) | called by muse, mutect2, varscan2
- SLC6A5 | c.466C>A p.Q156K | Missense Mutation (SNP) | VAF 63/269 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.525); called by muse, mutect2, varscan2
- SLCO5A1 | c.2076G>T p.L692F | Missense Mutation (SNP) | VAF 104/341 reads (30%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.851); called by muse, mutect2, varscan2
- SPIN3 | c.229C>T p.P77S | Missense Mutation (SNP) | VAF 17/105 reads (16%) | SIFT tolerated (0.12); PolyPhen benign (0.148); called by muse, mutect2, varscan2
- TAF4 | c.94C>T p.Q32* | Nonsense Mutation (SNP) | VAF 91/327 reads (28%) | called by muse, mutect2, varscan2
- TBC1D25 | c.1541G>T p.R514M | Missense Mutation (SNP) | VAF 22/124 reads (18%) | SIFT tolerated (0.05); PolyPhen benign (0.167); called by muse, mutect2, varscan2
- TCEAL6 | c.355del p.D119Tfs*16 | Frame Shift Del (DEL) | VAF 41/301 reads (14%) | called by mutect2, pindel, varscan2
- TCF7 | c.178G>A p.E60K | Missense Mutation (SNP) | VAF 35/189 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- TCHH | c.5360A>T p.Q1787L | Missense Mutation (SNP) | VAF 136/921 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- TET3 | c.1262G>T p.S421I | Missense Mutation (SNP) | VAF 198/855 reads (23%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.741); called by muse, mutect2, varscan2
- TEX15 | c.2580G>C p.L860F (on ENST00000256246; = p.L1243F on NM_001350162.2) | Missense Mutation (SNP) | VAF 36/306 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- THUMPD1 | c.1062G>T p.*354Yext*8 (on ENST00000381337; = p.*354Yext*26 on NM_017736.5 and 1 other RefSeq transcript) | Nonstop Mutation (SNP) | VAF 13/75 reads (17%) | called by muse, mutect2, varscan2
- TIMD4 | c.782C>A p.P261Q | Missense Mutation (SNP) | VAF 56/312 reads (18%) | SIFT tolerated (0.94); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- TIMD4 | c.781C>A p.P261T | Missense Mutation (SNP) | VAF 53/307 reads (17%) | SIFT tolerated (0.36); PolyPhen benign (0.098); called by muse, mutect2, varscan2
- TMEM150B | c.7G>T p.G3C | Missense Mutation (SNP) | VAF 50/258 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.536); called by muse, varscan2
- TMEM42 | c.416G>T p.G139V | Missense Mutation (SNP) | VAF 66/334 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TMEM59L | c.875C>G p.A292G | Missense Mutation (SNP) | VAF 69/375 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.94); called by muse, mutect2, varscan2
- TRAV7 | c.191G>C p.G64A | Missense Mutation (SNP) | VAF 217/524 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.405); called by muse, mutect2, varscan2
- TRPC4 | c.1765C>G p.Q589E | Missense Mutation (SNP) | VAF 33/249 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TTLL7 | c.111G>T p.K37N | Missense Mutation (SNP) | VAF 21/169 reads (12%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- TTN | c.64145C>A p.T21382N (on ENST00000591111; = p.T13958N on NM_003319.4) | Missense Mutation (SNP) | VAF 35/170 reads (21%) | PolyPhen benign (0.079); called by muse, mutect2, varscan2
- USP17L7 | c.534del p.H180Tfs*4 | Frame Shift Del (DEL) | VAF 110/382 reads (29%) | called by mutect2, pindel, varscan2
- USP22 | c.1017G>T p.W339C | Missense Mutation (SNP) | VAF 50/217 reads (23%) | SIFT tolerated (0.22); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- USP50 | c.125G>T p.G42V | Missense Mutation (SNP) | VAF 119/541 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- USP8 | c.2997A>C p.E999D | Missense Mutation (SNP) | VAF 31/201 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- VPS35 | c.2350C>G p.P784A | Missense Mutation (SNP) | VAF 94/444 reads (21%) | SIFT tolerated (0.47); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- WDR41 | c.1316G>C p.G439A | Missense Mutation (SNP) | VAF 59/359 reads (16%) | SIFT tolerated (0.64); PolyPhen benign (0); called by muse, mutect2, varscan2
- WDR45 | c.572A>T p.H191L (on ENST00000376372 / NM_001029896.2; = p.H192L on NM_007075.3) | Missense Mutation (SNP) | VAF 141/657 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- WDR70 | c.1165G>T p.D389Y | Missense Mutation (SNP) | VAF 153/561 reads (27%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- WDR81 | c.2750C>T p.T917I | Missense Mutation (SNP) | VAF 68/298 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- WFDC13 | c.10G>A p.V4M | Missense Mutation (SNP) | VAF 89/414 reads (21%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.444); called by muse, mutect2, varscan2
- XIRP2 | c.4046del p.T1349Kfs*19 (on ENST00000628543; = p.T1524Kfs*19 on NM_152381.6) | Frame Shift Del (DEL) | VAF 26/171 reads (15%) | called by mutect2, pindel, varscan2
- ZBTB3 | c.421C>T p.P141S | Missense Mutation (SNP) | VAF 20/530 reads (4%) | SIFT tolerated (0.17); PolyPhen benign (0.001); called by muse, mutect2
- ZNF185 | c.1983C>A p.C661* | Nonsense Mutation (SNP) | VAF 39/294 reads (13%) | called by muse, mutect2, varscan2
- ZNF366 | c.1333G>T p.G445C | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ZNF516 | c.1222G>T p.A408S | Missense Mutation (SNP) | VAF 77/430 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0.411); called by muse, mutect2, varscan2
- ZNF716 | c.1387C>A p.P463T | Missense Mutation (SNP) | VAF 52/322 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.484); called by mutect2, varscan2
- ZNF729 | c.1787G>A p.R596K | Missense Mutation (SNP) | VAF 68/376 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.177); called by muse, mutect2, varscan2
- ZNF91 | c.1979G>T p.C660F | Missense Mutation (SNP) | VAF 78/390 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- ZP1 | c.1242C>G p.D414E | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- ABCA5 | c.3708A>G p.S1236= | Silent (SNP) | VAF 52/194 reads (27%) | catalogued as COSV67016271; called by muse, varscan2
- ABCC4 | c.2293T>C p.L765= | Silent (SNP) | VAF 66/325 reads (20%) | called by muse, mutect2, varscan2
- ACSM1 | c.423G>C p.A141= | Silent (SNP) | VAF 61/328 reads (19%) | called by muse, mutect2, varscan2
- ADGRB3 | c.3855G>A p.T1285= | Silent (SNP) | VAF 58/261 reads (22%) | catalogued as rs192064488; called by muse, mutect2, varscan2
- ARRDC2 | c.687C>T p.A229= | Silent (SNP) | VAF 20/337 reads (6%) | called by muse, mutect2
- ATR | c.4797G>A p.L1599= | Silent (SNP) | VAF 79/423 reads (19%) | catalogued as COSV63389039, COSV63394177; called by muse, mutect2, varscan2
- C11orf16 | c.720C>A p.A240= | Silent (SNP) | VAF 122/553 reads (22%) | called by muse, mutect2, varscan2
- CACNG3 | c.942C>A p.P314= | Silent (SNP) | VAF 22/80 reads (28%) | catalogued as rs201263434, COSV50063834; called by muse, mutect2, varscan2
- CDCA7L | c.768G>A p.V256= | Silent (SNP) | VAF 17/137 reads (12%) | catalogued as rs1222671436; called by muse, mutect2, varscan2
- CERCAM | c.1278G>T p.R426= | Silent (SNP) | VAF 55/296 reads (19%) | called by muse, mutect2, varscan2
- CLMN | c.657G>T p.L219= | Silent (SNP) | VAF 34/80 reads (43%) | called by muse, mutect2
- CMPK2 | c.1101C>G p.L367= | Silent (SNP) | VAF 39/706 reads (6%) | called by muse, mutect2
- CNTNAP2 | c.1257G>A p.L419= | Silent (SNP) | VAF 248/819 reads (30%) | catalogued as rs773218141, COSV62204479; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL6A6 | c.2712C>A p.G904= | Silent (SNP) | VAF 27/140 reads (19%) | called by muse, mutect2, varscan2
- CPS1 | c.4416T>A p.L1472= | Silent (SNP) | VAF 161/771 reads (21%) | called by muse, mutect2, varscan2
- CRISPLD2 | c.1386G>T p.V462= | Silent (SNP) | VAF 53/224 reads (24%) | catalogued as COSV52283057; called by muse, mutect2, varscan2
- DIPK2B | c.1245G>T p.T415= | Silent (SNP) | VAF 56/294 reads (19%) | catalogued as COSV67640848; called by muse, mutect2, varscan2
- DMD | c.9051G>T p.L3017= | Silent (SNP) | VAF 107/683 reads (16%) | called by muse, mutect2, varscan2
- EPHA10 | c.819G>A p.A273= | Silent (SNP) | VAF 84/406 reads (21%) | catalogued as rs753228214, COSV57627702; called by muse, mutect2, varscan2
- EXTL3 | c.1392G>T p.L464= | Silent (SNP) | VAF 94/336 reads (28%) | catalogued as COSV99593915; called by muse, mutect2, varscan2
- GPR155 | c.231C>G p.V77= | Silent (SNP) | VAF 67/289 reads (23%) | called by muse, mutect2, varscan2
- GPR158 | c.2889T>A p.P963= | Silent (SNP) | VAF 317/1093 reads (29%) | called by muse, mutect2, varscan2
- GRIA3 | c.771G>C p.L257= | Silent (SNP) | VAF 49/220 reads (22%) | called by muse, mutect2, varscan2
- GRID1 | c.844C>A p.R282= | Silent (SNP) | VAF 76/274 reads (28%) | catalogued as COSV60012681; called by muse, varscan2
- GRIK2 | c.591T>G p.L197= | Silent (SNP) | VAF 57/180 reads (32%) | called by muse, mutect2, varscan2
- HOXA3 | c.219C>T p.R73= | Silent (SNP) | VAF 6/43 reads (14%) | called by muse, mutect2, varscan2
- HRNR | c.5857C>A p.R1953= | Silent (SNP) | VAF 144/5234 reads (3%) | catalogued as rs759446119, COSV64257294, COSV64261390; called by muse, mutect2
- HTR1A | c.474G>T p.S158= | Silent (SNP) | VAF 54/244 reads (22%) | catalogued as COSV100109159; called by mutect2, varscan2
- IBA57 | c.426A>G p.L142= | Silent (SNP) | VAF 48/326 reads (15%) | catalogued as rs772067451; called by muse, mutect2, varscan2
- IKBKB | c.19C>T p.L7= | Silent (SNP) | VAF 47/230 reads (20%) | called by muse, mutect2
- IL20RA | c.975G>A p.Q325= | Silent (SNP) | VAF 43/191 reads (23%) | called by muse, mutect2, varscan2
- INPP5D | c.3171G>T p.S1057= (on ENST00000445964 / NM_001017915.3; = p.S1056= on NM_005541.5) | Silent (SNP) | VAF 20/63 reads (32%) | catalogued as rs1273278293; called by muse, mutect2, varscan2
- JAKMIP3 | c.1098C>A p.T366= | Silent (SNP) | VAF 50/337 reads (15%) | called by muse, mutect2, varscan2
- KIF13B | c.4119A>T p.G1373= | Silent (SNP) | VAF 142/463 reads (31%) | called by muse, varscan2
- LDB3 | c.537C>T p.D179= | Silent (SNP) | VAF 86/245 reads (35%) | called by muse, mutect2, varscan2
- LY6K | c.321C>A p.P107= | Silent (SNP) | VAF 178/659 reads (27%) | called by mutect2, varscan2
- MED30 | c.108C>T p.I36= | Silent (SNP) | VAF 52/317 reads (16%) | catalogued as rs955078000, COSV52067172; called by muse, mutect2, varscan2
- MMS22L | c.1674C>G p.L558= | Silent (SNP) | VAF 35/151 reads (23%) | called by muse, mutect2, varscan2
- MORC1 | c.54C>T p.I18= | Silent (SNP) | VAF 46/257 reads (18%) | catalogued as COSV51722895; called by muse, mutect2, varscan2
- MTNR1A | c.24G>T p.L8= | Silent (SNP) | VAF 23/136 reads (17%) | called by muse, mutect2, varscan2
- MYH3 | c.1692C>T p.F564= | Silent (SNP) | VAF 30/612 reads (5%) | called by muse, mutect2
- MYOD1 | c.177C>A p.P59= | Silent (SNP) | VAF 39/170 reads (23%) | catalogued as COSV100000124, COSV100000172; called by muse, mutect2, varscan2
- NAA10 | c.222A>G p.S74= | Silent (SNP) | VAF 69/504 reads (14%) | catalogued as rs782033981; called by muse, mutect2, varscan2
- NES | c.3507G>A p.R1169= | Silent (SNP) | VAF 233/848 reads (27%) | catalogued as rs1188421790; called by muse, mutect2, varscan2
- NLRP14 | c.2709G>T p.T903= | Silent (SNP) | VAF 81/514 reads (16%) | catalogued as COSV55065882, COSV55072804; called by muse, mutect2, varscan2
- NOL4 | c.1356A>G p.Q452= | Silent (SNP) | VAF 79/368 reads (21%) | called by muse, mutect2, varscan2
- OBSCN | c.16470C>T p.T5490= | Silent (SNP) | VAF 112/675 reads (17%) | catalogued as rs569972697; called by muse, mutect2, varscan2
- OR14I1 | c.732T>A p.I244= | Silent (SNP) | VAF 34/232 reads (15%) | called by muse, mutect2, varscan2
- OR2AG2 | c.645G>T p.V215= | Silent (SNP) | VAF 87/530 reads (16%) | called by muse, mutect2, varscan2
- OR2C3 | c.12A>T p.I4= | Silent (SNP) | VAF 18/123 reads (15%) | catalogued as COSV100825797; called by muse, mutect2, varscan2
- OR2M3 | c.21C>A p.T7= | Silent (SNP) | VAF 27/150 reads (18%) | called by muse, mutect2, varscan2
- OR2T3 | c.276T>A p.T92= | Silent (SNP) | VAF 186/757 reads (25%) | called by muse, mutect2, varscan2
- OR5T2 | c.663T>A p.P221= | Silent (SNP) | VAF 6/44 reads (14%) | called by muse, mutect2
- OR6Y1 | c.927C>T p.T309= | Silent (SNP) | VAF 77/260 reads (30%) | called by muse, mutect2, varscan2
- PAK5 | c.297C>A p.S99= | Silent (SNP) | VAF 38/232 reads (16%) | called by muse, mutect2, varscan2
- PCDHB3 | c.1890G>C p.L630= | Silent (SNP) | VAF 130/763 reads (17%) | called by muse, mutect2, varscan2
- PCDHB5 | c.2175G>T p.S725= | Silent (SNP) | VAF 73/319 reads (23%) | catalogued as COSV50654181; called by muse, mutect2, varscan2
- PCDHB9 | c.1494G>T p.L498= | Silent (SNP) | VAF 126/622 reads (20%) | called by muse, mutect2, varscan2
- PHF21B | c.1318C>T p.L440= | Silent (SNP) | VAF 77/441 reads (17%) | called by muse, mutect2, varscan2
- PLD5 | c.114G>C p.A38= | Silent (SNP) | VAF 90/625 reads (14%) | called by muse, mutect2, varscan2
- PRAMEF20 | c.240T>A p.A80= | Silent (SNP) | VAF 173/877 reads (20%) | catalogued as COSV57080631; called by muse, mutect2, varscan2
- RCAN2 | c.84G>T p.L28= | Silent (SNP) | VAF 197/603 reads (33%) | called by muse, mutect2, varscan2
- RCN3 | c.525C>T p.A175= | Silent (SNP) | VAF 33/198 reads (17%) | catalogued as rs775089420, COSV54543337; called by muse, mutect2, varscan2
- RNF213 | c.14736C>A p.A4912= | Silent (SNP) | VAF 129/620 reads (21%) | catalogued as COSV60400513; called by muse, mutect2, varscan2
- RS1 | c.156A>T p.A52= | Silent (SNP) | VAF 98/756 reads (13%) | called by muse, mutect2, varscan2
- SCN2A | c.5160A>T p.L1720= | Silent (SNP) | VAF 85/489 reads (17%) | called by muse, mutect2, varscan2
- SIGLEC10 | c.33G>A p.L11= | Silent (SNP) | VAF 59/329 reads (18%) | called by muse, mutect2, varscan2
- SIRT6 | c.891G>T p.L297= | Silent (SNP) | VAF 25/74 reads (34%) | called by muse, mutect2, varscan2
- SLC12A5 | c.621C>T p.F207= (on ENST00000454036 / NM_001134771.2; = p.F184= on NM_020708.5) | Silent (SNP) | VAF 47/295 reads (16%) | called by muse, mutect2, varscan2
- SLIT3 | c.2046G>C p.R682= | Silent (SNP) | VAF 84/486 reads (17%) | called by muse, mutect2, varscan2
- SMIM20 | c.372T>C p.Y124= (on ENST00000614775; = p.Y23= on NM_001145432.1) | Silent (SNP) | VAF 37/152 reads (24%) | called by muse, mutect2, varscan2
- SOWAHD | c.696G>T p.A232= | Silent (SNP) | VAF 19/127 reads (15%) | catalogued as COSV59649864; called by muse, mutect2, varscan2
- SPATA21 | c.846T>A p.A282= | Silent (SNP) | VAF 105/529 reads (20%) | called by muse, mutect2, varscan2
- SPPL3 | c.1050T>C p.T350= | Silent (SNP) | VAF 82/192 reads (43%) | called by muse, mutect2, varscan2
- SRRM4 | c.726C>G p.P242= | Silent (SNP) | VAF 159/361 reads (44%) | called by muse, mutect2, varscan2
- STRIP1 | c.2094G>A p.L698= | Silent (SNP) | VAF 18/528 reads (3%) | called by muse, mutect2
- TAFA3 | c.192C>A p.S64= | Silent (SNP) | VAF 55/341 reads (16%) | called by muse, mutect2, varscan2
- TEX15 | c.7080A>G p.T2360= (on ENST00000256246; = p.T2743= on NM_001350162.2) | Silent (SNP) | VAF 47/130 reads (36%) | called by muse, mutect2, varscan2
- THSD7A | c.1695C>A p.A565= | Silent (SNP) | VAF 22/479 reads (5%) | catalogued as COSV70260951; called by muse, mutect2
- TLN1 | c.2088G>T p.S696= | Silent (SNP) | VAF 53/304 reads (17%) | catalogued as COSV59204434, COSV59206684; called by muse, mutect2, varscan2
- TRIM10 | c.15C>A p.A5= | Silent (SNP) | VAF 15/122 reads (12%) | catalogued as COSV100938824; called by muse, mutect2, varscan2
- TRPC3 | c.420C>T p.V140= (on ENST00000379645 / NM_001366479.2; = p.V67= on NM_003305.2) | Silent (SNP) | VAF 8/46 reads (17%) | called by muse, varscan2
- TRPC3 | c.327C>G p.L109= (on ENST00000379645 / NM_001366479.2; = p.L36= on NM_003305.2) | Silent (SNP) | VAF 28/148 reads (19%) | called by muse, varscan2
- UNC13B | c.3201G>A p.Q1067= | Silent (SNP) | VAF 114/452 reads (25%) | catalogued as rs761748704, COSV65932101; called by muse, mutect2, varscan2
- ZAN | c.1539C>A p.I513= | Silent (SNP) | VAF 18/127 reads (14%) | catalogued as COSV61811823; called by muse, mutect2, varscan2
- ZFP92 | c.1020C>G p.R340= | Silent (SNP) | VAF 24/207 reads (12%) | called by muse, mutect2, varscan2
- ZNF33B | c.1311G>T p.G437= | Silent (SNP) | VAF 90/304 reads (30%) | called by muse, mutect2, varscan2
- AC073316.1 | n.333C>A | RNA (SNP) | VAF 193/541 reads (36%) | called by muse, mutect2, varscan2
- AK2 | c.*4165G>C | 3'UTR (SNP) | VAF 16/406 reads (4%) | called by muse, mutect2
- AP000769.5 | chr11:65499370 C>A | 5'Flank (SNP) | VAF 50/330 reads (15%) | called by muse, mutect2, varscan2
- AP000769.5 | chr11:65499371 A>G | 5'Flank (SNP) | VAF 51/334 reads (15%) | called by muse, mutect2, varscan2
- ARHGAP24 | c.268+41G>A | Intron (SNP) | VAF 46/260 reads (18%) | called by muse, mutect2
- ATG4B | chr2:241637593 C>T | 5'Flank (SNP) | VAF 53/300 reads (18%) | catalogued as rs1405990423; called by muse, mutect2, varscan2
- BAIAP2L1 | c.955+12A>C | Intron (SNP) | VAF 170/476 reads (36%) | called by muse, varscan2
- C5orf64 | n.513-44650G>T | Intron (SNP) | VAF 40/278 reads (14%) | called by muse, varscan2
- CCDC144CP | n.2149G>T | RNA (SNP) | VAF 46/286 reads (16%) | called by muse, mutect2, varscan2
- COL4A2 | c.1433-547C>A | Intron (SNP) | VAF 20/64 reads (31%) | called by muse, mutect2, varscan2
- CTHRC1 | c.-14G>A | 5'UTR (SNP) | VAF 14/402 reads (3%) | catalogued as rs1473474522; called by muse, mutect2
- CYP2A7P1 | n.356G>T | RNA (SNP) | VAF 113/544 reads (21%) | called by muse, mutect2, varscan2
- EIF3IP1 | n.280G>T | RNA (SNP) | VAF 96/687 reads (14%) | called by muse, mutect2, varscan2
- EML3 | c.*178G>C | 3'UTR (SNP) | VAF 48/227 reads (21%) | called by muse, mutect2, varscan2
- FBLN1 | chr22:45502310 C>T | 5'Flank (SNP) | VAF 103/512 reads (20%) | catalogued as rs1434437287; called by muse, mutect2, varscan2
- FBLN1 | c.-43G>T | 5'UTR (SNP) | VAF 12/31 reads (39%) | called by muse, mutect2, varscan2
- FHL2 | chr2:105399438 G>A | 5'Flank (SNP) | VAF 67/337 reads (20%) | catalogued as rs1279930268; called by muse, mutect2, varscan2
- FMO9P | n.231C>T | RNA (SNP) | VAF 56/483 reads (12%) | called by muse, mutect2, varscan2
- GDI1 | c.*12C>G | 3'UTR (SNP) | VAF 56/352 reads (16%) | called by muse, varscan2
- GTF2H3 | c.93+632C>G | Intron (SNP) | VAF 65/395 reads (16%) | called by muse, mutect2, varscan2
- HAVCR1 | c.*28C>G | 3'UTR (SNP) | VAF 152/823 reads (18%) | catalogued as COSV100208308; called by muse, mutect2, varscan2
- ITGA3 | c.*175C>T | 3'UTR (SNP) | VAF 54/237 reads (23%) | called by muse, varscan2
- ITK | c.985+22G>T | Intron (SNP) | VAF 95/501 reads (19%) | called by muse, mutect2, varscan2
- KCND1 | c.1368+32G>T | Intron (SNP) | VAF 58/282 reads (21%) | called by muse, mutect2, varscan2
- LINC01583 | n.291A>C | RNA (SNP) | VAF 114/604 reads (19%) | called by muse, mutect2, varscan2
- LINC02054 | n.2532C>A | RNA (SNP) | VAF 49/191 reads (26%) | called by muse, mutect2, varscan2
- LINC02108 | n.82C>A | RNA (SNP) | VAF 13/57 reads (23%) | called by muse, mutect2, varscan2
- LRRC49 | c.500+3196C>T | Intron (SNP) | VAF 29/212 reads (14%) | catalogued as rs1415298193; called by muse, varscan2
- MAN2C1 | c.791-539del | Intron (DEL) | VAF 85/459 reads (19%) | called by mutect2, pindel*, varscan2
- MASP1 | c.1304-5377T>C | Intron (SNP) | VAF 70/466 reads (15%) | called by muse, mutect2, varscan2
- MFRP | chr11:119344668 C>A | 5'Flank (SNP) | VAF 205/923 reads (22%) | called by muse, mutect2, varscan2
- NCAPD3 | c.-16C>A | 5'UTR (SNP) | VAF 37/169 reads (22%) | called by muse, mutect2, varscan2
- NCR1 | c.70+25G>T | Intron (SNP) | VAF 95/440 reads (22%) | called by muse, mutect2, varscan2
- NELL2 | chr12:44876690 G>C | 5'Flank (SNP) | VAF 12/268 reads (4%) | called by muse, mutect2
- NR1H4 | c.-34C>A | 5'UTR (SNP) | VAF 72/208 reads (35%) | called by muse, mutect2, varscan2
- OVCH1 | chr12:29423275 C>A | 3'Flank (SNP) | VAF 40/279 reads (14%) | called by muse, mutect2, varscan2
- OVCH1 | chr12:29423276 T>A | 3'Flank (SNP) | VAF 38/274 reads (14%) | called by muse, mutect2, varscan2
- PLEKHM1P1 | n.1226C>T | RNA (SNP) | VAF 81/367 reads (22%) | called by muse, mutect2, varscan2
- POU3F4 | c.-34C>A | 5'UTR (SNP) | VAF 72/350 reads (21%) | catalogued as COSV100937167; called by muse, mutect2, varscan2
- PTPN12 | c.-14G>T | 5'UTR (SNP) | VAF 26/142 reads (18%) | catalogued as rs760435141; called by muse, mutect2, varscan2
- R3HDML | chr20:44355835 C>A | 3'Flank (SNP) | VAF 44/155 reads (28%) | called by muse, mutect2, varscan2
- RN7SL484P | chr15:99790423 C>A | 5'Flank (SNP) | VAF 80/426 reads (19%) | catalogued as rs750675726; called by muse, varscan2
- RUFY2 | chr10:68341260 G>C | 3'Flank (SNP) | VAF 55/463 reads (12%) | called by muse, mutect2, varscan2
- SHKBP1 | c.-11G>T | 5'UTR (SNP) | VAF 11/42 reads (26%) | catalogued as rs761564279; called by muse, mutect2, varscan2
- SLC25A26 | c.707+729G>T | Intron (SNP) | VAF 54/283 reads (19%) | called by muse, mutect2, varscan2
- SOHLH1 | c.*18G>T | 3'UTR (SNP) | VAF 26/131 reads (20%) | catalogued as COSV100039981; called by muse, mutect2, varscan2
- SPAG8 | c.*193G>A | 3'UTR (SNP) | VAF 20/118 reads (17%) | called by muse, mutect2, varscan2
- TESPA1 | c.207-23C>A | Intron (SNP) | VAF 84/205 reads (41%) | called by muse, mutect2, varscan2
- THSD4 | c.*3526G>A | 3'UTR (SNP) | VAF 3/26 reads (12%) | called by muse, mutect2
- TNPO3 | c.*145G>C | 3'UTR (SNP) | VAF 124/619 reads (20%) | called by muse, mutect2, varscan2
- TSPAN18 | c.-10-2865G>T | Intron (SNP) | VAF 207/970 reads (21%) | called by muse, mutect2, varscan2
- UBE2F | c.-121C>T | 5'UTR (SNP) | VAF 24/90 reads (27%) | catalogued as rs1290751298; called by muse, mutect2, varscan2
- ZNF419 | c.199+224G>T | Intron (SNP) | VAF 53/285 reads (19%) | called by muse, mutect2, varscan2
- ZNF890P | n.516C>A | RNA (SNP) | VAF 44/249 reads (18%) | called by muse, mutect2, varscan2
